Somatic mutation profile of tumor specimen TCGA-CK-5915-01A (aliquot TCGA-CK-5915-01A-11D-1650-10) from TCGA case TCGA-CK-5915, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 63.1 years (23,040 days).
Specimen TCGA-CK-5915-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce1f3a45-0a14-48f8-9169-773ec9e947af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CK-5915-10A (Blood Derived Normal), aliquot TCGA-CK-5915-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/866f931f-3963-461a-9425-258ad0b64838

The open-access MAF lists 94 somatic variants for this specimen: 63 protein-altering or splice-affecting, 30 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 30, Nonsense Mutation 5, Frame Shift Ins 4, Splice Site 2, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PKP2 | c.2484C>T p.G828= | Silent (SNP) | VAF 168/356 reads (47%) | catalogued as rs727504509, CS065607, COSV50728278; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- ADH1C | c.966C>T p.G322= | Splice Region (SNP) | VAF 255/432 reads (59%) | catalogued as rs1225012346, COSV101565180; called by muse, mutect2, varscan2
- AKAP13 | c.2456A>G p.H819R | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.074); catalogued as rs769879931, COSV63471751; called by muse, mutect2
- APC | c.1312+1G>C p.X438_splice | Splice Site (SNP) | VAF 182/208 reads (88%) | catalogued as CS021159, CS130068, COSV57326024, COSV57343038, COSV57388892; called by muse, mutect2, varscan2
- ATP2B4 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs770084350, COSV100397923, COSV58184732; called by muse, mutect2, varscan2
- BDP1 | c.4238T>A p.I1413N | Missense Mutation (SNP) | VAF 88/363 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV62435603; called by muse, mutect2, varscan2
- BHLHE41 | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 180/404 reads (45%) | catalogued as COSV54379888; called by muse, mutect2, varscan2
- C10orf120 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 92/221 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs1220862477, COSV61492848; called by muse, mutect2, varscan2
- CNNM1 | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 81/197 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as rs1164013204, COSV63202247, COSV63203808; called by muse, mutect2, varscan2
- CUX2 | c.1897C>T p.R633* | Nonsense Mutation (SNP) | VAF 17/27 reads (63%) | catalogued as rs763884354, COSV55650617; called by muse, mutect2, varscan2
- CYP1A2 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as rs201551575, COSV59661363; called by muse, mutect2, varscan2
- DIDO1 | c.2507T>C p.M836T | Missense Mutation (SNP) | VAF 136/218 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56635771; called by muse, mutect2
- DOCK3 | c.4120G>T p.V1374L | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV56527688, COSV99811526; called by muse, mutect2, varscan2
- DZIP1L | c.1253A>T p.K418M | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59524006; called by muse, mutect2, varscan2
- EPB41L4B | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 38/56 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV65799033; called by muse, mutect2, varscan2
- FAT2 | c.5671C>A p.L1891I | Missense Mutation (SNP) | VAF 63/194 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as rs764071826, COSV55831545; called by muse, mutect2, varscan2
- GABRA5 | c.1207G>T p.V403F | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as rs779166572, COSV59486843; called by muse, mutect2, varscan2
- GPATCH8 | c.262C>A p.L88I | Missense Mutation (SNP) | VAF 92/351 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100132622; called by muse, mutect2, varscan2
- HEXD | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs779870636, COSV60066435; called by muse, mutect2, varscan2
- INTS4 | c.20A>G p.K7R | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV71093277; called by muse, mutect2, varscan2
- KCTD2 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs1435125905, COSV59369791; called by muse, mutect2, varscan2
- KDM2B | c.3860C>T p.S1287F | Missense Mutation (SNP) | VAF 43/228 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV65639311, COSV65645964; called by muse, mutect2, varscan2
- KLC4 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs766293479, COSV52440038; called by muse, mutect2, varscan2
- KLK9 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs942944016, COSV51591599; called by muse, mutect2, varscan2
- KNL1 | c.5858G>A p.R1953H (on ENST00000346991 / NM_170589.5; = p.R1927H on NM_144508.5) | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs776587767, COSV61161371; called by muse, mutect2, varscan2
- LTB | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71333675; called by muse, mutect2, varscan2
- MIA3 | c.2504A>G p.K835R | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV104418927, COSV60518988; called by muse, mutect2, varscan2
- MTMR1 | c.1673C>T p.T558M | Missense Mutation (SNP) | VAF 175/189 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64892480; called by muse, mutect2, varscan2
- MYO3A | c.256T>C p.F86L | Missense Mutation (SNP) | VAF 102/223 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.088); catalogued as COSV99779508; called by muse, mutect2, varscan2
- NECTIN3 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as COSV60553865; called by muse, mutect2, varscan2
- NPTX2 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 65/115 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs200320030, COSV55719733; called by muse, mutect2, varscan2
- ODC1 | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 66/153 reads (43%) | catalogued as COSV52173792; called by muse, mutect2, varscan2
- OLFM3 | c.1120C>A p.L374I (on ENST00000338858 / NM_001288821.1; = p.L354I on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 167/291 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs1557680087, COSV58805504; called by muse, mutect2, varscan2
- PCDHB15 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as rs147410183, COSV50872050; called by muse, mutect2, varscan2
- PCDHB7 | c.1993G>A p.G665S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs782528648, COSV50799178, COSV99177125; called by muse, mutect2, varscan2
- PIK3CG | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1315748037, COSV63254488; called by muse, varscan2
- PRRG4 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 670/1545 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57674144; called by muse, mutect2, varscan2
- PTHLH | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 134/271 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as rs778459165, COSV52367483; called by muse, mutect2, varscan2
- RAD50 | c.3835C>T p.R1279C | Missense Mutation (SNP) | VAF 283/314 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs786201810, COSV99528906; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RFX1 | c.706G>A p.G236S | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs374974524, COSV54334173; called by muse, mutect2, varscan2
- RXFP2 | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as rs375862062, COSV53641860; called by muse, mutect2, varscan2
- S100A2 | c.192T>G p.D64E | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64185047; called by muse, mutect2, varscan2
- SCN4A | c.2131G>A p.V711M | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs764029151, COSV71129559; called by muse, mutect2, varscan2
- SCN5A | c.5239G>A p.V1747M (on ENST00000333535 / NM_198056.3; = p.V1746M on NM_000335.5) | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.741); catalogued as rs199473630, CM107420, COSV61122927; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- SGCZ | c.838G>C p.V280L | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.85); PolyPhen benign (0.125); catalogued as COSV66049818; called by muse, mutect2, varscan2
- SLC13A1 | c.19A>T p.I7F | Missense Mutation (SNP) | VAF 112/235 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV52017828; called by muse, mutect2, varscan2
- SLC25A46 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 252/868 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750732884, COSV63507096; called by muse, mutect2, varscan2
- SLC2A8 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 84/139 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372901354; called by muse, mutect2, varscan2
- SNTG1 | c.413T>G p.F138C | Missense Mutation (SNP) | VAF 268/575 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52478098, COSV99382465; called by muse, mutect2, varscan2
- SORBS1 | c.1999G>A p.G667R (on ENST00000361941 / NM_001034954.2; = p.G373R on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs149433187, COSV53359994; called by muse, mutect2, varscan2
- SOX6 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV57041699, COSV57049832; called by muse, mutect2, varscan2
- SPATA19 | c.317A>G p.E106G | Missense Mutation (SNP) | VAF 63/136 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.526); catalogued as COSV54485253; called by muse, mutect2, varscan2
- TBC1D20 | c.108A>G p.I36M | Missense Mutation (SNP) | VAF 171/575 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62613693; called by muse, mutect2, varscan2
- TGIF1 | c.183G>T p.Q61H (on ENST00000330513 / NM_001374396.1; = p.Q81H on NM_003244.4) | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57909842; called by muse, varscan2
- TMEM132D | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 79/192 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.808); catalogued as rs1287424489, COSV70603146; called by muse, mutect2, varscan2
- TMEM205 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.599); catalogued as rs745312230, COSV55793252; called by muse, mutect2, varscan2
- TNXB | c.7327C>T p.R2443C (on ENST00000647633; = p.R2196C on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/74 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs747302691, COSV64490630; called by muse, mutect2, varscan2
- TOP2B | c.200G>A p.R67H (on ENST00000264331 / NM_001330700.2; = p.R62H on NM_001068.3) | Missense Mutation (SNP) | VAF 124/508 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99979631; called by muse, varscan2
- ARID1A | c.608dup p.H203Qfs*197 | Frame Shift Ins (INS) | VAF 18/35 reads (51%) | called by mutect2, pindel, varscan2
- HECA | c.671dup p.C225Vfs*6 | Frame Shift Ins (INS) | VAF 24/62 reads (39%) | called by mutect2, pindel, varscan2
- LPAR6 | c.696dup p.V233Cfs*30 | Frame Shift Ins (INS) | VAF 23/43 reads (53%) | called by mutect2, pindel, varscan2
- MRPL47 | c.400_402+8del p.X134_splice | Splice Site (DEL) | VAF 71/174 reads (41%) | called by mutect2, pindel, varscan2
- RB1CC1 | c.3614dup p.Y1205* | Nonsense Mutation (INS) | VAF 410/1192 reads (34%) | called by mutect2, pindel
- TGIF1 | c.178_179dup p.Q61Yfs*19 (on ENST00000330513 / NM_001374396.1; = p.Q81Yfs*19 on NM_003244.4) | Frame Shift Ins (INS) | VAF 24/86 reads (28%) | called by pindel, varscan2
- BCAR3 | c.1734G>T p.G578= | Silent (SNP) | VAF 41/158 reads (26%) | catalogued as COSV99550681; called by muse, mutect2, varscan2
- C2CD6 | c.84G>A p.P28= | Silent (SNP) | VAF 196/362 reads (54%) | catalogued as COSV53801433; called by muse, mutect2, varscan2
- COL4A3 | c.1887G>A p.T629= | Silent (SNP) | VAF 50/93 reads (54%) | catalogued as rs201109911; called by muse, mutect2, varscan2
- DIP2A | c.4347C>T p.H1449= | Silent (SNP) | VAF 90/201 reads (45%) | catalogued as rs752202862, COSV59488667; called by muse, varscan2
- FAM47A | c.1440G>A p.P480= | Silent (SNP) | VAF 50/53 reads (94%) | catalogued as rs779152090, COSV100649674, COSV60500362; called by muse, mutect2, varscan2
- KIAA1217 | c.5643G>A p.Q1881= | Silent (SNP) | VAF 56/188 reads (30%) | catalogued as COSV56825207; called by muse, mutect2, varscan2
- MGAT3 | c.666C>T p.D222= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs1168080955, COSV57869084; called by muse, mutect2, varscan2
- MICAL2 | c.5718C>T p.N1906= | Silent (SNP) | VAF 38/80 reads (48%) | catalogued as rs761495736, COSV56289228; called by muse, mutect2, varscan2
- NEB | c.10980G>A p.R3660= | Silent (SNP) | VAF 98/232 reads (42%) | catalogued as rs570142622, COSV99421684; ClinVar: likely benign; called by muse, mutect2, varscan2
- NR5A1 | c.87G>A p.T29= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs750190008, COSV65295742; called by muse, varscan2
- PABPC3 | c.63C>T p.D21= | Silent (SNP) | VAF 50/181 reads (28%) | catalogued as COSV55807061; called by muse, mutect2, varscan2
- PCDHB12 | c.2112G>A p.S704= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs781820742, COSV53396323; called by muse, mutect2, varscan2
- PCSK2 | c.159C>T p.H53= | Silent (SNP) | VAF 193/287 reads (67%) | catalogued as rs752064526, COSV52735471; called by muse, mutect2, varscan2
- PGLS | c.207C>T p.S69= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as rs752588618, COSV53115652; called by muse, mutect2, varscan2
- PI4KA | c.2856G>A p.A952= | Silent (SNP) | VAF 43/175 reads (25%) | catalogued as rs146456725, COSV99745555; called by muse, mutect2, varscan2
- PIK3CG | c.87G>A p.A29= | Silent (SNP) | VAF 48/105 reads (46%) | catalogued as rs780581522, COSV63254643; called by muse, varscan2
- RFX3 | c.1692C>T p.S564= | Silent (SNP) | VAF 115/185 reads (62%) | catalogued as rs1320929379, COSV56526463; called by muse, mutect2, varscan2
- SEPTIN3 | c.30G>A p.T10= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs190850900; called by muse, mutect2, varscan2
- SETD2 | c.7356G>A p.S2452= | Silent (SNP) | VAF 125/269 reads (46%) | catalogued as rs368025625; called by muse, mutect2, varscan2
- SLC18A3 | c.573C>T p.F191= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV60319364; called by muse, mutect2, varscan2
- SMARCE1 | c.1167G>A p.S389= | Silent (SNP) | VAF 76/120 reads (63%) | catalogued as rs755995632, COSV52861931; ClinVar: likely benign; called by muse, mutect2, varscan2
- SVEP1 | c.1332G>A p.P444= | Silent (SNP) | VAF 71/239 reads (30%) | catalogued as rs370267821, COSV57043191; called by muse, mutect2, varscan2
- TMEM140 | c.441G>A p.P147= | Silent (SNP) | VAF 102/205 reads (50%) | catalogued as rs199612642, COSV51967751; called by muse, mutect2, varscan2
- UGT2B4 | c.1008G>A p.L336= | Silent (SNP) | VAF 81/301 reads (27%) | catalogued as rs1040264297, COSV59318392, COSV59321335; called by muse, varscan2
- UNC13D | c.1644G>A p.V548= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV52888140; called by muse, mutect2, varscan2
- UTP23 | c.705T>G p.S235= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV59125205; called by muse, mutect2
- VSTM2L | c.534C>T p.P178= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as rs1168500693, COSV65096725; called by muse, mutect2, varscan2
- ZIM2 | c.930T>C p.T310= | Silent (SNP) | VAF 256/550 reads (47%) | catalogued as COSV55650607; called by muse, mutect2
- ZNF106 | c.3540G>A p.T1180= | Silent (SNP) | VAF 138/209 reads (66%) | catalogued as rs768691962, COSV55522738; called by muse, mutect2, varscan2
- TCF7L2 | c.552+49371G>A | Intron (SNP) | VAF 54/96 reads (56%) | catalogued as rs1185307296, COSV60512597; called by mutect2, varscan2
